Somatic mutation profile of tumor specimen TCGA-VD-AA8Q-01A (aliquot TCGA-VD-AA8Q-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8Q, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.0 years (26,285 days).
Specimen TCGA-VD-AA8Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8181f9d8-402c-4acc-9f1f-b135eaa384c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8Q-10A (Blood Derived Normal), aliquot TCGA-VD-AA8Q-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d906d365-3a8f-4b76-99f8-7a0b50a1357e

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 25/83 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DEAF1 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1166736149, COSV58607924; called by muse, mutect2, varscan2
- FASTK | c.586T>G p.L196V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs1461067885; called by muse, mutect2, varscan2
- HOXB5 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1442101132; called by muse, varscan2
- LMBR1 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1233438390; called by muse, mutect2
- SRRM2 | c.7589G>A p.R2530Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1307066107, COSV51940226; called by muse, mutect2, varscan2
- UMODL1 | c.3014G>A p.R1005H (on ENST00000408910 / NM_001004416.2; = p.R1133H on NM_173568.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs768514919; called by muse, mutect2, varscan2
- DNAH17 | c.13135A>C p.M4379L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EXOC2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GAP43 | c.236A>C p.E79A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HOXB8 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- KRTAP9-3 | c.390C>G p.C130W | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RASA2 | c.241A>C p.K81Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTF1 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF180 | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACTRT2 | c.942G>A p.R314= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs771094841; called by muse, mutect2, varscan2
- CDH24 | c.1191C>T p.S397= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs780138714; called by muse, mutect2
- RARG | c.1101C>G p.R367= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- ZNF182 | c.579T>C p.H193= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
